Gene-level copy-number profile of tumor specimen TCGA-DX-AB2G-01A from TCGA case TCGA-DX-AB2G, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 36.2 years (13,239 days).
Specimen TCGA-DX-AB2G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7eaea461-c841-494b-ad9f-0ccc9bbddd44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/d060f1e5-3e37-4f5f-8b3e-da0ebd2aec3a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,529; copy number 3: 286; copy number 4: 51,359; copy number 5: 524; copy number 6: 614; copy number 7: 118; copy number 8: 454; copy number 9: 75; copy number 10: 8; copy number 11: 136; copy number 12: 5; copy number 13: 14; copy number 14: 2; copy number 15: 19; copy number 16: 52; copy number 17: 2; copy number 18: 199; copy number 19: 21; copy number 20: 32; copy number 21: 3; copy number 22: 103; copy number 23: 8; copy number 24: 12; copy number 25: 3; copy number 26: 5; copy number 27: 57; copy number 28: 2; copy number 29: 3; copy number 31: 6; copy number 33: 13; copy number 35: 33; copy number 36: 5; copy number 44: 33; copy number 45: 17; copy number 46: 2; copy number 47: 5; copy number 52: 9; copy number 54: 2; copy number 61: 26; copy number 63: 4; copy number 68: 3; copy number 72: 7; copy number 76: 1; copy number 82: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 931 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,125,216–87,276,584, 12 genes, copy number 23–52: AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr5:2,712,591–2,967,955, 7 genes, copy number 16: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2.
- chr6:91,815,843–92,790,665, 8 genes, copy number 9: AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3.
- chr6:96,889,315–97,283,217, 4 genes, copy number 9: NDUFAF4, RN7SL509P, KLHL32, MMS22L.
- chr6:107,490,106–110,180,004, 63 genes, copy number 9 (broad region; genes not listed).
- chr6:130,839,347–133,895,553, 65 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:135,055,033–158,926,571, 387 genes, copy number 11–27 (broad region; genes not listed).
- chr11:22,492,087–26,047,598, 28 genes, copy number 11: AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr12:46,183,063–46,270,017, 2 genes, copy number 46 (within-gene range 4–46): SLC38A1, AC025031.3.
- chr12:49,442,424–49,568,145, 4 genes, copy number 26 (within-gene range 4–26): AC125611.1, AC020612.4, KCNH3, MCRS1.
- chr12:50,392,383–51,217,708, 29 genes, copy number 15–45 (within-gene range 4–45): LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1.
- chr12:51,590,266–51,812,864, 2 genes, copy number 23 (within-gene range 4–23): SCN8A, HNRNPA3P10.
- chr12:52,164,115–52,652,211, 34 genes, copy number 16 (within-gene range 4–16): LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2.
- chr12:54,081,736–54,548,243, 27 genes, copy number 20 (within-gene range 4–20): AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L.
- chr12:55,311,835–55,427,192, 11 genes, copy number 16: OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr12:56,712,305–57,452,062, 33 genes, copy number 35 (within-gene range 4–35): NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC.
- chr12:57,619,527–58,105,935, 33 genes, copy number 44: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:58,544,124–58,813,060, 2 genes, copy number 17 (within-gene range 4–17): AC020637.1, LINC02388.
- chr12:58,920,639–59,064,238, 3 genes, copy number 15: AC068305.2, RPS6P22, AC068305.1.
- chr12:59,322,765–59,436,874, 3 genes, copy number 31 (within-gene range 4–31): AC108721.2, AC108721.1, RNU6-279P.
- chr12:59,596,029–60,269,686, 6 genes, copy number 29–68 (within-gene range 4–68): SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1.
- chr12:62,965,325–63,360,037, 9 genes, copy number 13: RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:65,278,643–65,491,430, 3 genes, copy number 33 (within-gene range 4–33): MSRB3, AC026124.1, KRT18P60.
- chr12:65,758,020–65,966,291, 5 genes, copy number 36: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:67,424,272–67,670,919, 6 genes, copy number 15: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:68,154,768–68,451,663, 7 genes, copy number 72: IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3.
- chr12:68,642,519–69,699,476, 33 genes, copy number 11–61 (within-gene range 4–61): ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:70,180,338–70,920,738, 11 genes, copy number 23–24 (within-gene range 4–60): LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:71,007,773–71,441,898, 4 genes, copy number 11 (within-gene range 4–11): AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:76,619,386–76,880,352, 7 genes, copy number 22: YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.
- chr12:78,863,993–79,503,396, 4 genes, copy number 63 (within-gene range 4–63): SYT1, AC090709.1, AC027288.3, MIR1252.
- chr12:80,343,515–80,937,925, 10 genes, copy number 10–82 (within-gene range 4–82): RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1.
- chr12:80,936,414–81,759,553, 7 genes, copy number 19–31 (within-gene range 4–31): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr12:89,282,223–89,353,271, 4 genes, copy number 20: RNU7-120P, MRPS6P4, DUSP6, AC024909.1.
- chr12:89,726,936–89,754,152, 3 genes, copy number 47: RNA5SP365, MRPL2P1, RNU6-148P.
- chr12:90,617,759–90,955,176, 4 genes, copy number 24–25 (within-gene range 4–25): AC112481.2, AC112481.1, CCER1, LINC00615.
- chr12:91,632,912–91,680,873, 3 genes, copy number 21: AC126175.1, AC126175.2, AC025254.1.
- chr12:91,984,976–92,226,557, 7 genes, copy number 18: LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA.
- chr12:94,260,548–94,282,844, 3 genes, copy number 12: AC073655.3, AC073655.1, AC073655.2.
- chr12:95,551,582–95,968,720, 10 genes, copy number 33: PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
